Somatic mutation profile of tumor specimen 56b488cf-a189-47a8-b4e2-d976eb (aliquot 56b488cf-a189-47a8-b4e2-d976eb_D6_1) from CPTAC case 11BR051, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65.4 years (23,877 days).
Specimen 56b488cf-a189-47a8-b4e2-d976eb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 937c6433-89c6-419f-a9e8-576e9723f5d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6b0937e4-0b78-4c0b-90ba-32fcf5 (Blood Derived Normal), aliquot 6b0937e4-0b78-4c0b-90ba-32fcf5_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ceea4c4-074c-4cbb-bb77-59b305261382

The open-access MAF lists 51 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Nonsense Mutation 2, Intron 2, Frame Shift Del 1, RNA 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 70/154 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1167609100, COSV58822670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPL | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 28/608 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as CM980081, COSV66376464, COSV66376627; called by muse, mutect2
- ARFGEF3 | c.6182C>T p.S2061F | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1450069394, COSV52458778; called by muse, mutect2
- BAIAP3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs145863608; called by muse, mutect2, varscan2
- BTBD11 | c.2573C>T p.T858M (on ENST00000280758 / NM_001018072.2; = p.T395M on NM_001017523.2) | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs199573507; called by muse, mutect2
- CENPF | c.7220G>A p.R2407Q | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs764028137; called by muse, mutect2, varscan2
- COPB1 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51446811; called by muse, mutect2, varscan2
- DEFB106B | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV59176573; called by mutect2, varscan2
- DNAH14 | c.8974G>A p.A2992T | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated, low confidence (0.36); catalogued as rs1474019727; called by muse, mutect2, varscan2
- DNAH5 | c.9013C>A p.Q3005K | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV54212802; called by muse, mutect2
- FAM126A | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV69472225; called by muse, mutect2
- FXR2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV51520342; called by muse, mutect2, varscan2
- FZD8 | c.802T>C p.F268L | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as rs1416205284, COSV65968148; called by muse, mutect2
- IGSF10 | c.6917C>T p.S2306L | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs997640867, COSV99196550; called by muse, mutect2
- MAP2K7 | c.932C>G p.S311W | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101209057, COSV67608825; called by muse, mutect2, varscan2
- MFF | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs1418789928; called by muse, mutect2, varscan2
- MYRF | c.1874C>T p.A625V (on ENST00000278836 / NM_001127392.3; = p.A616V on NM_013279.4) | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs150872059; called by muse, varscan2
- PELI3 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs150549632; called by muse, mutect2, varscan2
- SUPT3H | c.707C>T p.A236V (on ENST00000371460 / NM_181356.3; = p.A225V on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1254901665; called by muse, mutect2
- ACSF3 | c.680T>A p.V227D | Missense Mutation (SNP) | VAF 136/285 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by mutect2, varscan2
- ADGRB2 | c.481_493del p.C161Sfs*14 | Frame Shift Del (DEL) | VAF 116/494 reads (23%) | called by mutect2, pindel, varscan2
- ADGRG2 | c.2694G>T p.K898N (on ENST00000379869 / NM_001079858.3; = p.K895N on NM_005756.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ANK2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFHR1 | c.364A>C p.N122H | Missense Mutation (SNP) | VAF 137/499 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CFTR | c.1015A>T p.T339S | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMPD3 | c.2273T>C p.L758P | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LPA | c.201C>A p.Y67* | Nonsense Mutation (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- LRP2 | c.8071C>A p.H2691N | Missense Mutation (SNP) | VAF 77/477 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- NBEAL1 | c.7595C>T p.P2532L | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NTN1 | c.1608G>A p.W536* | Nonsense Mutation (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
- TENM3 | c.2741C>T p.T914I | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- XK | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2
- ZDHHC11B | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2
- BCL6 | c.198A>G p.K66= | Silent (SNP) | VAF 25/234 reads (11%) | called by muse, mutect2, varscan2
- BSN | c.288G>A p.P96= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV56527023; called by muse, mutect2, varscan2
- CSRNP1 | c.882C>A p.I294= | Silent (SNP) | VAF 86/285 reads (30%) | called by muse, mutect2, varscan2
- FSCN1 | c.1191C>T p.C397= | Silent (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- HPS1 | c.777G>A p.P259= | Silent (SNP) | VAF 20/272 reads (7%) | catalogued as rs140552558; called by muse, mutect2
- KMT2D | c.9303C>T p.P3101= | Silent (SNP) | VAF 62/348 reads (18%) | catalogued as COSV56485486; called by muse, mutect2, varscan2
- MUC12 | c.3171A>C p.S1057= (on ENST00000379442; = p.S914= on NM_001164462.1) | Silent (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2
- MUC16 | c.42609G>A p.Q14203= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as rs1179694415, COSV66690273; called by muse, mutect2
- OR4A15 | c.810T>A p.T270= | Silent (SNP) | VAF 20/335 reads (6%) | called by muse, mutect2
- RPGR | c.1524G>T p.L508= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- SAMD9L | c.3537C>T p.N1179= | Silent (SNP) | VAF 88/237 reads (37%) | catalogued as COSV100560663; called by muse, mutect2, varscan2
- SH3KBP1 | c.969G>A p.V323= | Silent (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- SLC10A3 | c.1086C>T p.L362= | Silent (SNP) | VAF 52/270 reads (19%) | catalogued as rs1196495210; called by muse, varscan2
- VARS1 | c.2085G>C p.R695= | Silent (SNP) | VAF 11/298 reads (4%) | called by muse, mutect2
- ELFN1 | c.-456+5629G>A | Intron (SNP) | VAF 52/236 reads (22%) | called by muse, varscan2
- GOLGA6L7 | c.462+144G>C | Intron (SNP) | VAF 14/321 reads (4%) | called by muse, mutect2
- OR2L1P | n.638G>T | RNA (SNP) | VAF 90/274 reads (33%) | called by muse, mutect2, varscan2
- VBP1 | c.*2G>T | 3'UTR (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
